Gene-level copy-number profile of tumor specimen ALCH-B4UX-TTP1-A from ALCHEMIST case ALCH-B4UX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.1 years (25,964 days).
Specimen ALCH-B4UX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e7692df-2bd2-4291-8291-15a4b51a3b2e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4UX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/78713a09-4698-44cf-8a19-1e9f7f7ef79f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 7,105; copy number 2: 51,241; copy number 3: 23; copy number 4: 19.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr19:48,968,130–48,993,310, 1 gene: GYS1.
- chr21:45,974,489–45,974,953, 1 gene: AJ011932.1.
- chr22:50,274,979–50,316,008, 2 genes (within-gene range 0–3): PLXNB2, CR559946.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,761. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
